Gene-level copy-number profile of tumor specimen TCGA-24-1424-01A from TCGA case TCGA-24-1424, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.2 years (24,545 days).
Specimen TCGA-24-1424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a6156dc4-597b-42ca-8e1a-258cebaa24fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1424-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b5357d6c-a860-4dd7-91d7-1113aabbc4f3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 125; copy number 2: 6,281; copy number 3: 17,620; copy number 4: 15,100; copy number 5: 10,113; copy number 6: 7,312; copy number 7: 1,290; copy number 8: 471; copy number 9: 204; copy number 10: 426; copy number 11: 73; copy number 12: 321; copy number 13: 47; copy number 14: 81; copy number 15: 125; copy number 16: 29; copy number 18: 92; copy number 20: 45; copy number 22: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1424-01A-01D-0472-01): tumor purity 0.76, ploidy 4.1, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,253 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–5,090,899, 218 genes, copy number 8–10 (broad region; genes not listed).
- chr1:5,561,709–5,668,295, 1 gene, copy number 8 (within-gene range 5–8): AL365255.1.
- chr1:5,862,672–7,769,706, 36 genes, copy number 8 (within-gene range 6–8): MIR4689, NPHP4, KCNAB2, CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672, AL591163.1, CAMTA1-DT, CAMTA1, AL590128.1, AL512330.1, RNU1-8P.
- chr1:181,668,749–183,418,380, 44 genes, copy number 7 (within-gene range 5–7): Metazoa_SRP, RNA5SP70, AL161734.2, AL161734.1, RN7SKP229, AL391477.1, ZNF648, AL355482.1, AL355482.2, LINC01344, AL390856.1, YPEL5P1, RNU6-152P, AL513480.1, EIF1P3, GLUL, TEDDM1, LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1.
- chr1:203,729,581–204,562,521, 33 genes, copy number 7: SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74.
- chr2:44,361,947–47,810,063, 70 genes, copy number 12–18 (within-gene range 6–18) (broad region; genes not listed).
- chr2:47,797,826–47,798,091, 1 gene, copy number 18: RPL36AP15.
- chr2:102,172,621–104,621,767, 36 genes, copy number 18: IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3.
- chr2:104,659,337–104,666,858, 1 gene, copy number 18: AC013402.1.
- chr2:105,600,703–106,368,876, 15 genes, copy number 18: AC018802.1, AC018802.2, NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1.
- chr2:112,138,385–112,346,258, 7 genes, copy number 7 (within-gene range 5–7): FBLN7, AC092645.1, ZC3H8, AC092645.2, ZC3H6, NDUFB4P6, AC115115.1.
- chr2:193,730,555–195,026,370, 13 genes, copy number 20: SEC61GP1, AC074290.1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, AC073973.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1.
- chr5:50,965,687–51,275,734, 7 genes, copy number 8: AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1.
- chr5:60,304,047–60,700,190, 9 genes, copy number 7 (within-gene range 4–7): RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1.
- chr6:46,652,915–67,210,480, 229 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:10,449,820–11,832,198, 14 genes, copy number 8: MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3.
- chr7:15,611,212–28,180,795, 232 genes, copy number 10–20 (within-gene range 5–20) (broad region; genes not listed).
- chr7:53,316,149–53,947,804, 11 genes, copy number 7: RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854.
- chr7:54,201,224–54,202,421, 1 gene, copy number 7: AC092848.1.
- chr10:743,992–14,462,142, 237 genes, copy number 8–18 (within-gene range 6–18) (broad region; genes not listed).
- chr10:29,373,027–36,995,585, 129 genes, copy number 8–10 (broad region; genes not listed).
- chr12:70,638,073–82,686,632, 154 genes, copy number 7–11 (broad region; genes not listed).
- chr17:59,859,479–60,666,280, 40 genes, copy number 13: TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:77,877,330–83,095,122, 235 genes, copy number 9–14 (broad region; genes not listed).
- chr19:7,112,255–8,262,421, 58 genes, copy number 8: INSR, AC119396.1, AC008878.3, AC119396.2, ARHGEF18, PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2, RPS27AP19, RETN, MCEMP1, AC008763.3, TRAPPC5, FCER2, CLEC4G, AC008763.4, CD209, RPL21P129, CLEC4M, CLEC4GP1, EXOSC3P2, EVI5L, PRR36, AC010336.3, LYPLA2P2, 5S_rRNA, LRRC8E, AC010336.1, MAP2K7, AC010336.4, TGFBR3L, AC010336.2, SNAPC2, CTXN1, AC010336.5, TIMM44, AC010336.7, ELAVL1, AC010336.6, AC008946.1, CCL25, FBN3, AC022146.1, CERS4, AC022146.2.
- chr19:8,580,240–8,610,735, 1 gene, copy number 11 (within-gene range 3–11): ADAMTS10.
- chr19:8,630,635–8,698,795, 3 genes, copy number 11: NFILZ, AC243312.1, ACTL9.
- chr19:9,383,581–9,435,571, 2 genes, copy number 14: AC011451.3, ZNF266.
- chr19:17,075,781–17,214,537, 1 gene, copy number 10 (within-gene range 4–10): MYO9B.
- chr19:17,152,588–18,782,333, 99 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr19:19,320,829–22,861,594, 175 genes, copy number 12 (within-gene range 5–12) (broad region; genes not listed).
- chr19:23,739,195–32,678,300, 115 genes, copy number 10–22 (broad region; genes not listed).
- chr19:37,093,019–37,210,512, 1 gene, copy number 8 (within-gene range 4–8): AC012309.1.
- chr19:37,181,579–39,846,379, 139 genes, copy number 8–15 (broad region; genes not listed).
- chr20:31,257,664–64,313,132, 886 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 125. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
